TCGA case TCGA-DX-AB3C — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Synovial-like Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94359edf-7208-4b4c-ad7c-4064974de818

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 27 years; Vital status: Alive.

Diagnoses (3)
1. Synovial sarcoma, spindle cell (the primary disease): ICD-O-3 morphology code: 9041/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 27.5 years (10,034 days); Year of diagnosis: 2008; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5.3; Tumor length measurement: 7.1; Tumor width measurement: 6.9.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Metastasis of diagnosis 1 (Synovial sarcoma, spindle cell), site: Lung, NOS. Age at diagnosis: 29.0 years (10,601 days); Days to diagnosis: 567 days (1.6 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 0.5.
3. Recurrence of diagnosis 1 (Synovial sarcoma, spindle cell), site: Lower limb, NOS. Age at diagnosis: 32.6 years (11,891 days); Days to diagnosis: 1,857 days (5.1 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 567 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 567 days (1.6 years).
- Days to follow up: 576 days (1.6 years); Disease response: Tumor Free.
- Day 1,857 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lower limb, NOS; Days to recurrence: 1,857 days (5.1 years).
- Days to follow up: 2,169 days (5.9 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-AB3C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 560 mg.
  Slide TCGA-DX-AB3C-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-AB3C-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-AB3C-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Synovial Sarcoma - Monophasic; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 48; Days from index date to pharmaceutical treatment ended: 181; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 90; Days from index date to pharmaceutical treatment ended: 181; Pharmaceutical therapy drug name: Etoposide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 48; Days from index date to pharmaceutical treatment ended: 89; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Radiation treatment: Days from index date to radiation therapy started: 91; Days from index date to radiation therapy ended: 133; Radiation therapy type: External; Radiation total dose: 5580; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 31; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,169 days; disease-specific survival: no event (censored), 2,169 days; disease-free interval: event (new tumor event after initially disease-free), 567 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 567 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-AB3C-01A-11D-A416-01): tumor purity 0.98, ploidy 1.9, whole-genome doublings 0.
